Somatic mutation profile of tumor specimen 0DGSRB from CCDI case PBBPMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.8 years (298 days).
Specimen 0DGSRB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4887cf40-3321-4db3-bba6-43dc58fac6dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGSR4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b314234b-9569-4f06-b6c1-b128f86db8f4

The open-access MAF lists 3 somatic variants for this specimen: 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPEP2 | c.1111C>T p.L371= | Silent (SNP) | VAF 54/381 reads (14%) | called by muse, mutect2, varscan2
- IFNA7 | c.*40C>G | 3'UTR (SNP) | VAF 50/220 reads (23%) | catalogued as rs994521835; called by muse, mutect2, varscan2
- TRMU | chr22:46335689 C>G | 5'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
